Gene-level copy-number profile of tumor specimen ALCH-B3DD-TTP1-A from ALCHEMIST case ALCH-B3DD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.7 years (22,542 days).
Specimen ALCH-B3DD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee180ffa-e3a9-475d-8c3c-7f13da3b1178.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/acc204fe-2b3d-4c7b-aa97-2c17692ad07b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 3,291; copy number 2: 54,616; copy number 3: 391; copy number 4: 34; copy number 5: 24; copy number 6: 4; copy number 7: 2; copy number 8: 2; copy number 9: 1; copy number 12: 1; copy number 13: 1; copy number 15: 1; copy number 27: 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:116,590,385–116,609,175, 1 gene: PNLIPRP1.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr19:53,787,597–53,824,394, 7 genes: AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2, NLRP12.
- chr22:18,110,331–18,177,397, 3 genes (within-gene range 0–1): TUBA8, AC008079.1, USP18.
- chr22:25,351,418–25,405,377, 1 gene: LRP5L.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,650,231–74,851,551, 5 genes, copy number 6–15: GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2.
- chr8:126,556,323–127,419,050, 1 gene, copy number 5 (within-gene range 4–5): PCAT1.
- chr8:127,072,694–128,564,679, 23 genes, copy number 5: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr15:77,941,442–77,944,582, 1 gene, copy number 6: COMMD4P1.
- chr16:2,644,084–2,645,214, 1 gene, copy number 13: AC141586.2.
- chr20:64,290,187–64,313,132, 2 genes, copy number 27: CICP4, LINC00266-1.
- chr21:44,133,610–44,210,114, 4 genes, copy number 7–12 (within-gene range 1–12): GATD3A, LINC01678, AP001056.2, AP001056.1.
- chr22:37,180,166–37,199,385, 1 gene, copy number 9 (within-gene range 2–9): C1QTNF6.

Autosomal genes at a single copy (total copy number 1): 1,490. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
